Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A95Z, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A95Z-06A (Metastatic).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Procedures/Addenda Attached

ICD-O-3
Melanoma NOS 8720/3
Site: Subcutaneous tissue
④ Flank C49.6
W 5/16/14

Specimen(s) Received:
METASTATIC MELANOMA LEFT FLANK

FINAL DIAGNOSIS

SKIN, METASTATIC MELANOMA LEFT FLANK, EXCISION:

- MALIGNANT MELANOMA, METASTASIS

NOTE: There is a large nodule of malignant melanoma within the subcutaneous fat, with foci of necrosis en masse and numerous mitotic figures. The neoplastic cells are positive for Melan A and practically negative for HMB45. The margins are negative.

Pathologist:

*** Report Electronically Signed Out ***

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

Received fresh labeled with the patient's name and "metastatic melanoma left flank" is a 9.5 x 8.0 x 5.0 cm tan-red, firm nodule which is partially surfaced by a 16.0 x 7.0 cm tan, unremarkable skin. One edge of the skin displays an unoriented stitch which is arbitrarily designated at 12:00 by the prosector. The specimen has been previously incised and inked orange. The specimen is inked (9-12-3:00 black, 3-6-9:00 blue) and serially sectioned. The nodule has a tan-white to yellow, heterogeneous, lobulated, indurated cut surface and grossly abuts the inked margin. The nodule does not involve the overlying skin. A gross photograph is taken of one cross section. Received separately in the same container is a 6.5 x 2.0 x 1.5 cm irregular soft tissue with orange ink along one aspect, consistent with additional portion of nodule. Representative sections are submitted in 4 cassettes with separate tissue in cassette 4.

Summary of Stains Performed and Reviewed

	Count
HMB-45 *	1
Melan-A *	1

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the supplier. It has not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and Internal controls stained appropriately.

[page 2 of 3]
Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1] METASTATIC MELANOMA LEFT FLANK	4	[Undes]	(4)	(No Description)

Procedures/Addenda

MOLECULAR DIAGNOSTIC TESTING - PCR Pathologist:

Status: Signed Out

Findings (Results)

PCR-SSCP analysis of BRAF gene was performed on [REDACTED]

BRAF gene V600E mutation IS NOT identified.

Analytic specific reagent (ASR) is used. This test was developed and its performance characteristics determined by the [REDACTED]. The test has not been cleared or approved by the U.S. Food and Drug Administration. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Interpretation

Approximately 50% of cutaneous melanoma harbor BRAF mutation that leads to activation of cell signaling for tumor proliferation. The vast majority of the mutations are the V600E amino acid substitution. Recent studies show that melanomas with the V600E mutation are more aggressive and less sensitive to chemotherapy. However, melanoma patients with the V600E mutation have been found to have a 63% reduction of mortality and a 74% reduction of disease progression when treated with Vemurafenib (PLX4032) in phase III clinical trial studies. Therefore, patients with advanced melanoma harboring the BRAF V600E mutation may benefit from specific inhibitor therapy. Arkenau HT et al. Target BRAF for patients with melanoma. Br J Cancer 104:392, 2011. Flaherty KT et al. Inhibition of mutated, activated BRAF in metastatic melanoma. N Engl J Med 363:809, 2010. Chapman PB et al. Improved survival with Vemurafenib melanoma with BRAF V600E mutation. N Engl J Med 364:2507, 2011.

BRAF V600E mutation is not detected in the specimen tested.

Testing was performed by the [REDACTED]

TUMOR GENOTYPING

Pathologist:

Status: Signed Out

Findings (Results)

Analysis was performed on: [REDACTED] part 1, block 1.
Tumor / specimen type: Metastatic Melanoma/Left Flank.

Selected regions of tumor DNA were "pre-amplified" prior to mutational testing because of [REDACTED]

[page 3 of 3]
the small amount of total DNA available from this specimen.

None of the mutations listed below was detected in this tumor.

In all tests in which a mutation was "not detected," only normal (wild type) sequence was identified.

Gene	Mutation: Protein	Mutation: DNA	Result
BRAF	G469A	1406G>C	not detected
	V600K	1798_1799GT>AA	not detected
	V600E	1799T>A	not detected
	V600M	1798G>A	not detected
NRAS	G12R	34G>C	not detected
	G12C	34G>T	not detected
	G12S	34G>A	not detected
	G12D	35G>A	not detected
	G12A	35G>C	not detected
	G12V	35G>T	not detected
	G13R	37G>C	not detected
	G13C	37G>T	not detected
	G13D	38G>A	not detected
	G13V	38G>T	not detected
	G13A	38G>C	not detected
	Q61K	181C>A	not detected
	Q61P	182A>C	not detected
	Q61L	182A>T	not detected
	Q61R	182A>G	not detected
	Q61H	183A>T	not detected
	Q61H	183A>C	not detected

Note: Mutations are described at the protein level using the single-letter amino acid code. X indicates the absence of an amino acid (i.e., a nonsense mutation, caused by creation of a stop codon in the DNA), and "fs" indicates a frameshift mutation. Mutations are described at the DNA level using the numbering of the reference gene's coding sequence (rather than the genomic sequence). Standard mutation nomenclature is used, according to guidelines of the Human Genome Variation Society (<http://www.hgvs.org/mutnomen/>).

Methodology

The patient sample was enriched for tumor by manual or laser-assisted dissection of formalin-fixed, paraffin-embedded (FFPE) tissue sections. DNA was extracted using a commercially available kit and quantitated on a spectrophotometer. "Pre-amplification" to expand the amount of DNA for analysis is performed by highly multiplexed PCR using 20 ng of total DNA and primer pairs for varying subsets of the assays in the full panel of tests. Following pre-amplification, the reaction mixture is diluted 1:20 and aliquots of this diluted pool of PCR products are separately assayed, in conjunction with control samples, for subsets of the mutations listed above. Mutation detection was performed using -based assays run on a Real-Time PCR instrument. Assay sensitivities were determined using serial dilutions (with normal DNA) of DNA from positive control samples. Whenever possible, positive controls consisted of DNA from human cell lines bearing the particular mutation being assayed. For those mutations not present in any available cell line, assay sensitivity testing was performed on positive control FFPE tumor tissues or DNA plasmids engineered to contain the mutant allele. All assays have been determined to have a minimum sensitivity of 50% heterozygous mutant cells (25% mutant alleles).

These tests were developed with class I analyte-specific reagents (ASRs) and the performance characteristics of the tests were determined by the , as required by the regulations of the Clinical Laboratory Improvement Amendments of 1988 (CLIA-1988). Pursuant to these regulations, the ASRs used in these tests have been established and verified for accuracy and precision. These tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for clinical application. This test is used for clinical purposes and should not be regarded as investigational or for research. Testing was performed by the . This laboratory is certified under the requirements of CLIA-1988 as qualified to perform high complexity clinical testing. Additional information about the tests performed by the laboratory is available upon request.

Interpretation

None of the mutations listed above was detected in this tumor.

Source: NCI Genomic Data Commons file b2edc087-4fcd-44c7-8bd6-8f8a3524dd14 (TCGA-DA-A95Z.3FB8693E-F050-46DE-BDFB-307D53713FFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).